TCGA case TCGA-MQ-A4LM — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ab19ae8-c095-48d6-b1aa-0f5ae75c6e68

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 158 days.

Diagnoses (3)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 67.6 years (24,704 days); Year of diagnosis: 2002; Method of diagnosis: Imaging; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Clinical Trial Agent; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant). Age at diagnosis: 67.9 years (24,817 days); Days to diagnosis: 113 days; Prior treatment: Yes.
3. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Thorax, NOS. Age at diagnosis: 68.0 years (24,824 days); Days to diagnosis: 120 days; Prior treatment: Yes.

Follow-up (3 entries)
- Day 113 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Days to progression: 113 days.
- Day 120 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 120 days.
- Follow-up contact recording only the day: day 158.

Exposures
- Exposure type: Asbestos; Exposure duration years: 10.
- Occupation duration years: 10; Occupation type: Building Frame and Related Trades Workers.

Family history
- Relative with cancer history: yes; Relationship type: Grandparent; Relationship primary diagnosis: Throat Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MQ-A4LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-MQ-A4LM-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MQ-A4LM-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: He grounded granite counter tops for a living for about 10 years.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma; Mesothelioma detection method: Thorascopy.
- Drug treatment: Clinical trial drug classification: COPA Chelating Agent.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 158 days; disease-specific survival: event status not recorded, 158 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 113 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MQ-A4LM-01A-11D-A34B-01): tumor purity 0.34, ploidy 1.69, whole-genome doublings 0.
